Somatic mutation profile of tumor specimen TCGA-BQ-5883-01A (aliquot TCGA-BQ-5883-01A-11D-1589-08) from TCGA case TCGA-BQ-5883, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 79.1 years (28,877 days).
Specimen TCGA-BQ-5883-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f59dcb4f-7a7e-4ea2-b31a-7b28f0db3c65.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BQ-5883-11A (Solid Tissue Normal), aliquot TCGA-BQ-5883-11A-01D-1589-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9cb471e9-d8a6-4026-8d20-f568efbeca94

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 13, Silent 4, Frame Shift Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 12/37 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AP2A2 | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 20/251 reads (8%) | catalogued as COSV59960126; called by muse, mutect2
- ARFGEF2 | c.4282G>A p.V1428I | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs759412939, COSV64212011; called by muse, mutect2, varscan2
- AURKB | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as rs866443565, COSV60244374; called by muse, mutect2
- CEMIP2 | c.3935C>G p.P1312R | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.342); catalogued as COSV65486961; called by muse, mutect2
- MMP11 | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs764798232, COSV53156119; called by muse, mutect2, varscan2
- OR10AD1 | c.137T>C p.I46T | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV59612537, COSV59612668; called by muse, mutect2, varscan2
- PCDHA9 | c.1819C>T p.L607F | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV65324320; called by muse, mutect2
- RBBP8 | c.1701C>G p.C567W | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.078); catalogued as COSV59092307; called by muse, mutect2
- RNF207 | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1372043495; called by muse, mutect2
- SMPD4 | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1163781830, COSV60079991, COSV60081087; called by mutect2, varscan2
- STON2 | c.156G>C p.E52D | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.015); catalogued as COSV50844028; called by muse, mutect2
- TDRD1 | c.2382A>T p.K794N | Missense Mutation (SNP) | VAF 13/190 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52590227; called by muse, mutect2
- THSD7B | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.679); catalogued as COSV55681516; called by muse, mutect2
- ADCY8 | c.1755_1758del p.Y585* | Frame Shift Del (DEL) | VAF 22/204 reads (11%) | called by pindel, varscan2
- CERS3 | c.693del p.T232Pfs*3 | Frame Shift Del (DEL) | VAF 17/124 reads (14%) | called by mutect2, pindel, varscan2
- ENTPD3 | c.1326T>A p.T442= | Silent (SNP) | VAF 7/175 reads (4%) | catalogued as COSV57194236; called by muse, mutect2
- KIAA1109 | c.12441C>G p.G4147= | Silent (SNP) | VAF 7/91 reads (8%) | catalogued as COSV52670867; called by muse, mutect2
- LTF | c.834T>C p.S278= | Silent (SNP) | VAF 5/77 reads (6%) | catalogued as rs957924967, COSV51607724; called by muse, mutect2
- MFAP1 | c.126A>C p.G42= | Silent (SNP) | VAF 12/212 reads (6%) | catalogued as COSV51038882; called by muse, mutect2
